Gene-level copy-number profile of tumor specimen TCGA-VQ-AA6D-01A from TCGA case TCGA-VQ-AA6D, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,090 days).
Specimen TCGA-VQ-AA6D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f3b08470-c06e-4264-ba77-283e17637e74.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VQ-AA6D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/df2cac49-a70f-413a-97bf-1d6ae24939d0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 11,437; copy number 2: 43,464; copy number 3: 4,033; copy number 4: 630; copy number 5: 51; copy number 6: 54; copy number 7: 1; copy number 8: 5; copy number 11: 19; copy number 14: 37; copy number 20: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VQ-AA6D-01A-11D-A40Z-01): tumor purity 0.82, ploidy 1.93, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 73 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr5:59,703,606–60,033,020, 2 genes: MIR582, AC034234.1.
- chr6:2,227,803–2,230,261, 1 gene: AL035693.1.
- chr19:31,100,304–33,927,625, 65 genes (broad region; genes not listed).
- chr20:14,757,563–14,935,363, 3 genes: RPS10P2, MACROD2-AS1, AL138808.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 172 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:21,678,298–22,101,360, 20 genes, copy number 5 (within-gene range 2–5): USP48, AL590103.1, LDLRAD2, HSPG2, AL590556.1, AL590556.2, CELA3B, AL590556.3, RN7SL386P, RNU6-1022P, CELA3A, RN7SL186P, RNU6-776P, LINC01635, LINC00339, CDC42, CDC42-AS1, AL031281.1, CDC42-IT1, MPHOSPH6P1.
- chr1:234,604,269–234,647,571, 4 genes, copy number 5: IRF2BP2, AL160408.2, LINC00184, AL160408.5.
- chr1:234,957,231–234,980,804, 3 genes, copy number 6: AL391832.1, AL391832.2, AL391832.3.
- chr2:85,354,394–85,391,752, 1 gene, copy number 5 (within-gene range 2–5): ELMOD3.
- chr2:85,367,585–85,460,252, 9 genes, copy number 5: Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA.
- chr4:167,648,430–170,033,031, 36 genes, copy number 6: PHBP14, RN7SKP188, AC105148.1, AC116634.1, ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1, PALLD, BTF3L4P4, PALLD-AS1, RNU6-1336P, RPL9P16, AC080188.1, AC080188.2, CBR4, RNU6-853P, RNY4P17, AC021151.1, SH3RF1, RPL6P12, AC096741.1, NEK1, AC084724.1, CLCN3, HPF1, PTGES3P3, AC079768.1, AC079768.3, AC079768.4, LINC02275, AC079768.2, AC084866.2, AC084866.1, MFAP3L.
- chr6:106,695,535–106,788,148, 4 genes, copy number 5–11 (within-gene range 3–11): LINC02526, LINC02532, RNU6-117P, MIR587.
- chr6:135,181,308–135,260,933, 4 genes, copy number 6: MYB, MYB-AS1, MIR548A2, AL023693.1.
- chr8:17,801,345–17,861,069, 2 genes, copy number 8 (within-gene range 3–8): AC027117.2, AC027117.1.
- chr8:108,443,601–108,787,594, 5 genes, copy number 5 (within-gene range 3–5): EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:112,222,928–113,436,939, 4 genes, copy number 5 (within-gene range 3–5): CSMD3, AC024996.1, RPL30P16, MIR2053.
- chr12:52,897,187–52,952,906, 2 genes, copy number 5: KRT8, KRT18.
- chr12:53,012,104–53,013,921, 1 gene, copy number 5: AC068888.2.
- chr13:98,553,243–98,752,672, 7 genes, copy number 6: AL356423.1, STK24-AS1, NUS1P4, CYCSP35, CALM2P4, RN7SL60P, SLC15A1.
- chr13:98,832,084–98,872,005, 2 genes, copy number 6: DOCK9-AS1, AL161420.1.
- chr17:39,546,104–39,864,312, 16 genes, copy number 11 (within-gene range 2–11): RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1.
- chr19:28,435,388–28,727,680, 1 gene, copy number 20 (within-gene range 1–20): AC005394.2.
- chr19:28,491,864–28,632,728, 1 gene, copy number 20 (within-gene range 1–20): AC005394.1.
- chr19:28,602,379–30,713,538, 43 genes, copy number 8–20: AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr19:41,708,657–41,756,737, 1 gene, copy number 7 (within-gene range 1–7): AC243967.1.
- chr20:35,520,852–35,529,652, 2 genes, copy number 6: FO393401.1, C20orf173.
- chr20:49,503,874–49,729,842, 4 genes, copy number 5 (within-gene range 3–5): PTGIS, B4GALT5, RN7SL197P, SNRPFP1.

Autosomal genes at a single copy (total copy number 1): 11,437. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
